FM case AD2194 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/db12e4de-a089-434d-9b71-2bffc5c91cb1

Male, 66.3 years: Non-small cell carcinoma (ICD-O-3 8046/3) of the lung; metastasis biopsied or resected from the other ill-defined sites. Tumor nuclei on the sequenced sample's slide: 35% (pathologist estimate recorded by GDC). Sample type: Metastatic.
